TARGET case TARGET-10-PAPNTA — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/31eabad2-2eda-54b5-b728-4cb4ac623ee8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead; Days to death: 1,405 days (3.8 years).

Diagnoses (1)
1. Precursor B-cell lymphoblastic leukemia: ICD-O-3 morphology code: 9836/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 4.3 years (1,563 days); Year of diagnosis: 2006; Days to last follow up: 1,405 days (3.8 years).

Biospecimens (2 samples)
- Sample TARGET-10-PAPNTA-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PAPNTA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
